Somatic mutation profile of tumor specimen TCGA-CD-A486-01A (aliquot TCGA-CD-A486-01A-11D-A24D-08) from TCGA case TCGA-CD-A486, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 68.1 years (24,879 days).
Specimen TCGA-CD-A486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1491e314-c0f2-47fe-a554-4ce77b15068e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A486-10A (Blood Derived Normal), aliquot TCGA-CD-A486-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4d158f4-3e55-4058-a381-69bab8d88ab3

The open-access MAF lists 100 somatic variants for this specimen: 80 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 67, Silent 20, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Ins 2, In Frame Del 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKP2 | c.2484C>T p.G828= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs727504509, CS065607, COSV50728278; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.531_548del p.H178_S183del | In Frame Del (DEL) | VAF 12/33 reads (36%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA10 | c.3048+2T>C p.X1016_splice | Splice Site (SNP) | VAF 20/130 reads (15%) | catalogued as COSV52230540; called by muse, mutect2
- ANO8 | c.3211G>A p.G1071R | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.84); catalogued as rs749119999, COSV50201874; called by muse, mutect2, varscan2
- CAPG | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55706746; called by muse, mutect2, varscan2
- CD163 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs780185045, COSV63136816; called by muse, mutect2, varscan2
- CDC23 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143830444; called by muse, mutect2, varscan2
- CELF2 | c.634A>G p.T212A (on ENST00000416382 / NM_001025077.3; = p.T219A on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59983590; called by muse, mutect2, varscan2
- CEP128 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53678932; called by muse, mutect2, varscan2
- CLU | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV57065913, COSV57068615; called by muse, mutect2, varscan2
- CUBN | c.4621C>T p.R1541W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs146824506; called by muse, mutect2, varscan2
- DCAF12L1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284451282, COSV64422872; called by muse, mutect2, varscan2
- DLC1 | c.3821C>G p.A1274G (on ENST00000276297 / NM_001348081.2; = p.A837G on NM_006094.5) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs769211247, COSV52330439; called by muse, mutect2, varscan2
- DNAJC13 | c.785T>C p.L262S | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV53459171; called by muse, mutect2, varscan2
- ECI2 | c.104C>A p.A35E (on ENST00000380118 / NM_206836.3; = p.A5E on NM_006117.2) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV60989625; called by muse, mutect2, varscan2
- ETAA1 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV55475416; called by muse, mutect2, varscan2
- FAR1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61384462; called by muse, mutect2, varscan2
- FBN1 | c.2773C>A p.L925M | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV57314690; called by muse, mutect2, varscan2
- FBXO3 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV55768269; called by muse, mutect2
- FLG | c.6712C>G p.P2238A | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV64250972; called by muse, varscan2
- GAS6 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59856397; called by muse, mutect2, varscan2
- GIMAP1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs1345838972, COSV56187780; called by muse, mutect2, varscan2
- GTF2B | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs1249692707, COSV65137719; called by muse, mutect2, varscan2
- HEATR5B | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51859721; called by muse, mutect2, varscan2
- HERC2 | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55340686, COSV55352753; called by muse, mutect2, varscan2
- INPP5K | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 135/196 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141189913; called by muse, mutect2, varscan2
- KCNN2 | c.754G>A p.A252T (on ENST00000264773; = p.A464T on NM_021614.4) | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.195); catalogued as rs1375840468, COSV53300303; called by muse, mutect2, varscan2
- KIAA2026 | c.3356C>A p.A1119E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.663); catalogued as COSV67358087; called by muse, mutect2, varscan2
- KRT25 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs754517768, COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- LARP7 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60522429; called by muse, mutect2, varscan2
- LRP1B | c.12129G>A p.W4043* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV67280101; called by muse, mutect2, varscan2
- MAP3K15 | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100135912; called by muse, mutect2, varscan2
- MARCHF5 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV62769958, COSV62770896; called by muse, mutect2, varscan2
- MINAR1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs542925690, COSV59587107; called by muse, mutect2, varscan2
- MRGPRX3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs201248611, COSV66934095; called by muse, mutect2, varscan2
- MRPL51 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57519526; called by muse, mutect2, varscan2
- MUSK | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769657813, COSV51882214; called by muse, mutect2, varscan2
- NAA25 | c.1921A>G p.R641G | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV55709616; called by muse, mutect2, varscan2
- NBN | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1335655343, COSV55372251, COSV55377497; ClinVar: uncertain significance; called by muse, mutect2
- NOTCH1 | c.2524G>T p.G842W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099377, COSV99489477; called by muse, mutect2, varscan2
- NPAP1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755681616, COSV100274534, COSV61510472; called by muse, mutect2, varscan2
- NRIP1 | c.1057A>T p.I353F | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV59660712; called by muse, mutect2, varscan2
- NRXN1 | c.3899T>C p.V1300A | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV60525642; called by muse, mutect2, varscan2
- OR4X1 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV60724119; called by muse, mutect2, varscan2
- PAPOLG | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.036); catalogued as rs780627523, COSV53182282; called by muse, mutect2, varscan2
- PAQR9 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV61419205; called by muse, mutect2, varscan2
- PCDHGA8 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.087); catalogued as COSV53979968; called by muse, mutect2, varscan2
- PDZD2 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753954633, COSV56874511; called by muse, mutect2, varscan2
- PDZD2 | c.5533G>A p.V1845I | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs748596911, COSV56874522; called by muse, mutect2, varscan2
- PEX11A | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100261455, COSV55585386; called by muse, mutect2, varscan2
- PLCL1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV101407324; called by muse, mutect2, varscan2
- RHOBTB1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as rs1404174046, COSV61960418; called by muse, mutect2, varscan2
- ROBO1 | c.3508A>G p.R1170G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV71398983; called by muse, mutect2, varscan2
- ROBO1 | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as COSV71398987; called by muse, mutect2
- SEL1L2 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs746232756, COSV53148352; called by muse, mutect2
- SERINC4 | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV51052007; called by muse, mutect2, varscan2
- SIPA1L1 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV62174216; called by muse, mutect2, varscan2
- SLBP | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59184497; called by muse, mutect2, varscan2
- SLC25A4 | c.741C>T p.A247= | Splice Region (SNP) | VAF 18/43 reads (42%) | catalogued as rs776229952, COSV55669797; called by muse, mutect2, varscan2
- SLC5A1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363968834, COSV56688669; called by muse, mutect2, varscan2
- SLCO6A1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1470127220, COSV65809287; called by muse, mutect2, varscan2
- SSH3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs143770446; called by muse, mutect2, varscan2
- STARD10 | c.836_844del p.A279_G281del | In Frame Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs770220463; called by mutect2, varscan2
- STK36 | c.3781C>G p.Q1261E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55331272; called by muse, mutect2, varscan2
- STXBP5 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs34215830; called by muse, mutect2, varscan2
- SYPL1 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV50579631; called by muse, mutect2, varscan2
- SYT16 | c.280T>G p.C94G | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV70860265; called by muse, mutect2, varscan2
- TMEM132E | c.2123G>A p.R708H (on ENST00000321639; = p.R798H on NM_001304438.2) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58700935; called by muse, mutect2, varscan2
- TNFRSF14 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV63185970, COSV63188666; called by muse, mutect2, varscan2
- TPO | c.2093A>C p.N698T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV61095274; called by muse, mutect2
- TTN | c.34654C>T p.P11552S (on ENST00000591111; = p.P10625S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/244 reads (17%) | PolyPhen benign (0.003); catalogued as rs1387140150, COSV60384839; called by muse, mutect2, varscan2
- TTN | c.21301C>T p.P7101S (on ENST00000591111; = p.P6174S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | PolyPhen probably damaging (0.996); catalogued as COSV60384851; called by muse, mutect2, varscan2
- UTP20 | c.7717G>A p.D2573N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV55373335; called by muse, mutect2, varscan2
- VPS13D | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1375929155, COSV50651063; called by muse, mutect2, varscan2
- XRCC5 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV67534910; called by muse, mutect2, varscan2
- ZMAT4 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); catalogued as rs751036977, COSV52716553; called by muse, mutect2, varscan2
- ANO2 | c.2594_2602dup p.F867_D868insAQF (on ENST00000356134 / NM_001278597.3; = p.F871_D872insAQF on NM_001278596.3) | In Frame Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- G3BP1 | c.828dup p.V277Sfs*11 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- HECTD2 | c.1144dup p.I382Nfs*22 | Frame Shift Ins (INS) | VAF 19/67 reads (28%) | called by mutect2, varscan2
- LGALS3BP | c.106del p.R36Afs*20 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- SYNCRIP | c.305_307dup p.Y102_R103insN | In Frame Ins (INS) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- ADAD2 | c.684G>A p.S228= (on ENST00000315906 / NM_001145400.2; = p.S300= on NM_139174.4) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs73252701, COSV51895555; called by muse, mutect2
- ARID5A | c.228C>T p.I76= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs559775215, COSV62591845; called by muse, mutect2, varscan2
- ATP2C2 | c.780C>T p.V260= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as rs765553044, COSV52293132; called by muse, mutect2, varscan2
- CDC25A | c.279C>T p.D93= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV56772502; called by muse, mutect2, varscan2
- CEP85L | c.153T>C p.N51= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV63821290, COSV63821832; called by muse, mutect2, varscan2
- CHD6 | c.7857T>G p.P2619= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV64695044; called by muse, mutect2, varscan2
- DSEL | c.240A>G p.G80= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV59495306; called by muse, mutect2, varscan2
- EIF3J | c.654A>G p.K218= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV56002914; called by muse, mutect2, varscan2
- FRY | c.7938C>T p.T2646= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- HEY2 | c.804C>T p.A268= | Silent (SNP) | VAF 35/246 reads (14%) | catalogued as COSV100856275, COSV64240839; called by muse, mutect2, varscan2
- IGHM | c.1140C>T p.S380= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs782220166; called by muse, mutect2
- KCTD13 | c.633C>A p.L211= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100442200, COSV58161827; called by muse, mutect2, varscan2
- MKRN3 | c.519G>A p.S173= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs774367502, COSV58812534; called by muse, mutect2, varscan2
- MUTYH | c.687C>T p.T229= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs780747266, COSV58344254; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR52B6 | c.720C>T p.I240= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs780883371, COSV61448424; called by muse, mutect2, varscan2
- OR8B4 | c.375C>T p.I125= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV62070694; called by muse, mutect2, varscan2
- SAAL1 | c.174T>C p.D58= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV55517514; called by muse, mutect2, varscan2
- TBCK | c.1062A>T p.T354= (on ENST00000273980 / NM_001163436.4; = p.T291= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV56763514; called by muse, mutect2
- TEP1 | c.4689C>T p.T1563= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV53001280, COSV99402735; called by muse, mutect2, varscan2
